Somatic mutation profile of tumor specimen TCGA-D3-A1QB-06A (aliquot TCGA-D3-A1QB-06A-11D-A19A-08) from TCGA case TCGA-D3-A1QB, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 76.7 years (28,007 days).
Specimen TCGA-D3-A1QB-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 816ed04e-c132-4de3-b651-f03d5f60022a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A1QB-10A (Blood Derived Normal), aliquot TCGA-D3-A1QB-10A-01D-A19A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/325aa0af-e28c-4214-8dc9-c8429ebf77c1

The open-access MAF lists 445 somatic variants for this specimen: 293 protein-altering or splice-affecting, 143 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 260, Silent 143, Nonsense Mutation 23, Splice Site 6, RNA 5, Splice Region 3, Intron 2, 3'UTR 1, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL4A4 | c.3743G>A p.G1248E | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs548799639, COSV61632205; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 23/144 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RB1 | c.1735C>T p.R579* | Nonsense Mutation (SNP) | VAF 7/31 reads (23%) | hotspot (GDC flag); catalogued as rs121913305, CM941206, COSV57294317, COSV99923811; ClinVar: pathogenic; called by muse, mutect2
- ABCB11 | c.2563G>A p.G855R | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as CM071526, COSV55590596; called by muse, mutect2, varscan2
- ABCB11 | c.1073C>T p.T358I | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV55588099, COSV55590614; called by muse, mutect2, varscan2
- ABCC3 | c.4136C>T p.T1379I | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV53321714; called by muse, mutect2, varscan2
- ABCD2 | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV58051835; called by muse, mutect2, varscan2
- AC097636.1 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as COSV71309487; called by muse, mutect2, varscan2
- ACADSB | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV62550700; called by muse, mutect2, varscan2
- ACE | c.2651G>A p.W884* | Nonsense Mutation (SNP) | VAF 28/140 reads (20%) | catalogued as COSV52006814; called by muse, mutect2, varscan2
- ACOT4 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs751971603, COSV58335653; called by muse, mutect2, varscan2
- ACSL6 | c.1975C>T p.H659Y (on ENST00000379240; = p.H684Y on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.864); catalogued as COSV57298527; called by muse, mutect2, varscan2
- ACTR3 | c.461C>T p.T154I | Missense Mutation (SNP) | VAF 47/263 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as COSV54301053; called by muse, mutect2, varscan2
- ACTRT2 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.021); catalogued as COSV65759381; called by muse, mutect2, varscan2
- ADCY5 | c.3637G>A p.G1213S | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774848359, COSV59197832; called by muse, mutect2, varscan2
- ADGRF1 | c.1783A>G p.I595V | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.04); catalogued as rs1320089065, COSV51945511; called by muse, mutect2, varscan2
- AGR3 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs746862695, COSV60037702; called by muse, mutect2, varscan2
- AGRN | c.2165G>A p.G722E | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV65068340, COSV65069601; called by muse, mutect2, varscan2
- AMBRA1 | c.1207C>T p.P403S (on ENST00000458649 / NM_001367468.1; = p.P313S on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); catalogued as rs748267527, COSV54053936; called by muse, varscan2
- ANKRD30A | c.1133G>A p.G378E (on ENST00000611781; = p.G322E on NM_052997.2) | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (1); PolyPhen probably damaging (0.931); catalogued as COSV64610179; called by muse, mutect2, varscan2
- ANXA13 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 17/168 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs992360945, COSV51623321; called by muse, mutect2
- AP002748.5 | c.591G>A p.R197= | Splice Region (SNP) | VAF 17/73 reads (23%) | catalogued as COSV59148673; called by muse, mutect2, varscan2
- AP1B1 | c.2584C>T p.Q862* | Nonsense Mutation (SNP) | VAF 5/21 reads (24%) | catalogued as COSV58017578; called by muse, mutect2, varscan2
- ARHGAP21 | c.3763C>T p.R1255C | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57605752; called by muse, mutect2
- ARMC5 | c.938T>G p.L313R | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.864); catalogued as COSV51656423; called by muse, mutect2, varscan2
- ASPHD1 | c.863G>A p.G288D | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58099424; called by muse, mutect2, varscan2
- ATN1 | c.3298C>T p.P1100S | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.91); catalogued as rs947688180, COSV57546841; called by muse, mutect2, varscan2
- ATP8B4 | c.3506G>A p.W1169* | Nonsense Mutation (SNP) | VAF 21/107 reads (20%) | catalogued as COSV52715577; called by muse, mutect2, varscan2
- BAG3 | c.1157C>T p.S386F | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.191); catalogued as rs756178548, COSV64842016; called by muse, mutect2, varscan2
- BRWD1 | c.3784A>G p.K1262E | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.054); catalogued as rs780700995, COSV60895820; called by muse, mutect2, varscan2
- C17orf75 | c.754C>T p.L252F | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV56752841; called by muse, mutect2
- C1QTNF9 | c.719A>T p.K240I | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV59657112; called by muse, mutect2, varscan2
- CABIN1 | c.6602C>T p.S2201F | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs267606192, COSV54081737; called by muse, mutect2, varscan2
- CACHD1 | c.1957C>T p.P653S | Missense Mutation (SNP) | VAF 40/242 reads (17%) | SIFT tolerated (1); PolyPhen probably damaging (0.979); catalogued as rs1202710311, COSV51553231; called by muse, mutect2, varscan2
- CACNA1H | c.560C>T p.S187L | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs774551478, COSV61990453; called by muse, mutect2, varscan2
- CACNG3 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as COSV50065622; called by muse, mutect2, varscan2
- CAPN9 | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs375897039; called by muse, mutect2, varscan2
- CAPSL | c.200G>A p.G67E | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV68438109; called by muse, mutect2, varscan2
- CCDC110 | c.1084C>T p.P362S | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.698); catalogued as COSV56870778; called by muse, mutect2, varscan2
- CCDC63 | c.25A>G p.R9G | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV57526789; called by muse, mutect2, varscan2
- CCDC68 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.271); catalogued as COSV61603665; called by muse, mutect2
- CCER1 | c.754G>A p.G252S | Missense Mutation (SNP) | VAF 70/386 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV62646836; called by muse, mutect2, varscan2
- CCL20 | c.192-1G>A p.X64_splice | Splice Site (SNP) | VAF 10/42 reads (24%) | catalogued as rs1175636236, COSV62591365; called by muse, mutect2
- CCL26 | c.74-1G>A p.X25_splice | Splice Site (SNP) | VAF 10/51 reads (20%) | catalogued as rs1554528159, COSV50013646; called by muse, mutect2, varscan2
- CCR2 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 49/252 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.343); catalogued as rs866454124, COSV52748666; called by muse, mutect2, varscan2
- CCS | c.545G>A p.R182K | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.243); catalogued as COSV59579091; called by muse, mutect2, varscan2
- CD244 | c.55G>A p.G19S | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as rs1240975686, COSV100458114; called by muse, mutect2
- CDC25A | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1216333941, COSV56770628; called by muse, mutect2, varscan2
- CDCP1 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.469); catalogued as rs370335828; called by muse, mutect2, varscan2
- CDH11 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.788); catalogued as rs755899936, COSV51759406; called by muse, mutect2, varscan2
- CDSN | c.763G>A p.V255M | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52538104; called by muse, mutect2, varscan2
- CEACAM7 | c.242G>A p.G81E | Missense Mutation (SNP) | VAF 38/163 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV50072923; called by muse, mutect2, varscan2
- CELSR2 | c.4000C>T p.P1334S | Missense Mutation (SNP) | VAF 88/386 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as rs1395900004, COSV54771776; called by muse, mutect2, varscan2
- CENPU | c.295C>G p.P99A | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.142); catalogued as COSV55657684, COSV55658715; called by muse, varscan2
- CEP57 | c.76G>A p.G26R | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as COSV57688394; called by muse, mutect2, varscan2
- CEP89 | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59864238; called by muse, mutect2, varscan2
- CFAP91 | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 42/217 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.844); catalogued as COSV56341066; called by muse, mutect2, varscan2
- CHRM3 | c.397C>T p.R133* | Nonsense Mutation (SNP) | VAF 10/100 reads (10%) | catalogued as rs867578112, COSV55084917; called by muse, mutect2, varscan2
- CHST10 | c.70T>C p.F24L | Missense Mutation (SNP) | VAF 72/327 reads (22%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.011); catalogued as COSV51805254; called by muse, mutect2, varscan2
- CIITA | c.1615C>T p.R539* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | catalogued as COSV60857106; called by mutect2, varscan2
- CLCNKB | c.2048C>T p.P683L | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs368764495, COSV100989727; called by muse, mutect2, varscan2
- CLEC3B | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.136); catalogued as COSV56109791, COSV99944581; called by muse, mutect2, varscan2
- CNBD1 | c.736C>T p.L246F | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.216); catalogued as COSV72976110; called by muse, mutect2
- CNGB1 | c.357C>G p.H119Q | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.023); catalogued as COSV51900858; called by muse, mutect2
- COL11A2 | c.3926G>A p.G1309E (on ENST00000341947 / NM_080680.3; = p.G1202E on NM_080679.2) | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1008221204, COSV59496878; called by muse, mutect2, varscan2
- COL4A1 | c.2384C>T p.S795F | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.805); catalogued as COSV65425654; called by muse, mutect2, varscan2
- COL4A4 | c.3818G>A p.G1273E | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61632201; called by muse, mutect2, varscan2
- COL4A5 | c.3080G>A p.G1027E | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM050562, COSV60358130; called by muse, mutect2, varscan2
- COL6A3 | c.1940C>T p.S647L | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55089389; called by muse, mutect2, varscan2
- CRHBP | c.746G>A p.G249E | Missense Mutation (SNP) | VAF 100/562 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57188560; called by muse, mutect2, varscan2
- CRYGD | c.17T>C p.L6P | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV52205273; called by muse, mutect2, varscan2
- CSMD3 | c.1027C>T p.Q343* | Nonsense Mutation (SNP) | VAF 14/110 reads (13%) | catalogued as rs868150877, COSV52142728, COSV52181099; called by muse, mutect2, varscan2
- CSN2 | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.063); catalogued as COSV61992147, COSV61992639; called by muse, mutect2, varscan2
- CUL9 | c.967C>T p.L323F | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as COSV52728521; called by muse, mutect2
- CYTH4 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as rs373316484; called by muse, mutect2, varscan2
- DIAPH3 | c.3542C>T p.P1181L | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); catalogued as rs781283166, COSV100930786; called by muse, mutect2
- DNAH10 | c.2653G>A p.D885N (on ENST00000409039; = p.D824N on NM_207437.3) | Missense Mutation (SNP) | VAF 33/166 reads (20%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.739); catalogued as rs776514851, COSV68989002, COSV68991354; called by muse, mutect2, varscan2
- DNAH5 | c.13560G>A p.W4520* | Nonsense Mutation (SNP) | VAF 26/116 reads (22%) | catalogued as COSV54224649; called by muse, mutect2, varscan2
- DNAH5 | c.7237C>T p.L2413F | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.167); catalogued as COSV54224661; called by muse, mutect2
- DNAH5 | c.5297C>T p.S1766F | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.71); PolyPhen benign (0.02); catalogued as COSV54224682; called by muse, mutect2, varscan2
- DNAH9 | c.1528A>T p.N510Y | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.051); catalogued as COSV52349591; called by muse, mutect2, varscan2
- DOCK2 | c.5134G>A p.E1712K | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.129); catalogued as COSV56958769, COSV99915365; called by muse, mutect2, varscan2
- DPP6 | c.1064C>T p.S355F (on ENST00000377770 / NM_001364500.2; = p.S293F on NM_001936.5) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.8); catalogued as COSV59600152; called by muse, mutect2, varscan2
- DSG1 | c.1704G>A p.M568I | Missense Mutation (SNP) | VAF 21/170 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV57135271; called by muse, mutect2, varscan2
- DUSP26 | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.885); catalogued as rs200165319, COSV56360588, COSV56361109; called by muse, mutect2, varscan2
- DYM | c.515C>T p.S172L | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV99492357; called by muse, mutect2, varscan2
- DYNC2I1 | c.2008C>T p.P670S | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as rs1176299495, COSV68104798; called by muse, mutect2, varscan2
- ENG | c.119G>A p.G40D | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.539); catalogued as rs11545665, COSV61227437; called by muse, mutect2, varscan2
- ENO3 | c.176G>A p.G59E | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs935129522, COSV99850490; called by muse, mutect2
- ERBB3 | c.3772G>A p.E1258K | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.775); catalogued as rs1231170513, COSV57253324; called by muse, mutect2, varscan2
- ERBB4 | c.1913G>A p.W638* | Nonsense Mutation (SNP) | VAF 15/98 reads (15%) | catalogued as rs747144499, COSV53525763, COSV53532686; called by muse, mutect2, varscan2
- ERP27 | c.799A>T p.K267* | Nonsense Mutation (SNP) | VAF 18/54 reads (33%) | catalogued as COSV56763353, COSV99844456; called by muse, varscan2
- ERVW-1 | c.950G>A p.R317K | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.191); catalogued as rs1554362269, COSV71259410; called by muse, varscan2
- ESRRB | c.32G>A p.S11N | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV55061542; called by muse, mutect2, varscan2
- ETV4 | c.934G>C p.V312L | Missense Mutation (SNP) | VAF 43/221 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.233); catalogued as rs147888887, COSV52253369; called by muse, mutect2, varscan2
- F2 | c.602G>A p.G201D | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0.006); catalogued as COSV61315824; called by muse, mutect2, varscan2
- FAM160B2 | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs1028555787, COSV57158510; called by muse, mutect2, varscan2
- FAM222B | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.996); catalogued as COSV100368118; called by muse, mutect2, varscan2
- FAM91A1 | c.949G>A p.V317I | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs757876509, COSV58236871; called by muse, mutect2
- FAS | c.263G>A p.G88E | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58238694; called by muse, mutect2, varscan2
- FAT4 | c.12860G>A p.G4287E | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58685287; called by muse, mutect2, varscan2
- FCRL1 | c.1076C>T p.S359L | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); catalogued as COSV63825166; called by muse, mutect2, varscan2
- FCSK | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as rs1193929656, COSV55370790; called by muse, mutect2, varscan2
- FLG | c.11953G>A p.D3985N | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as COSV64241805, COSV64245865; called by muse, mutect2, varscan2
- FLRT1 | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.179); catalogued as COSV55360553; called by muse, mutect2, varscan2
- FNDC7 | c.1213G>A p.A405T | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54753556; called by muse, mutect2, varscan2
- FPR2 | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as COSV60672843; called by muse, mutect2, varscan2
- GDAP1 | c.710C>T p.P237L | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55185624; called by muse, mutect2, varscan2
- GLYAT | c.113G>A p.G38E | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53539356; called by muse, mutect2, varscan2
- GOT2 | c.971C>T p.A324V | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as COSV55331617; called by muse, mutect2, varscan2
- GOT2 | c.400G>T p.G134* | Nonsense Mutation (SNP) | VAF 15/93 reads (16%) | catalogued as COSV55331625; called by muse, mutect2, varscan2
- GPR156 | c.1507G>A p.D503N | Missense Mutation (SNP) | VAF 50/188 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV59939868; called by muse, mutect2, varscan2
- GPR37L1 | c.428T>A p.V143E | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV66162294; called by muse, mutect2, varscan2
- GPRIN3 | c.1696C>T p.P566S | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.324); catalogued as COSV60884912; called by muse, mutect2, varscan2
- GRHL1 | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV100257413, COSV61408148, COSV61409722; called by muse, mutect2, varscan2
- GRIN2B | c.4208C>T p.S1403F | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); catalogued as COSV74205565; called by muse, mutect2, varscan2
- GRIN2B | c.3937G>A p.E1313K | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.107); catalogued as COSV74205462; called by muse, mutect2, varscan2
- GSG1 | c.436G>A p.E146K (on ENST00000651961 / NM_001080555.4; = p.E110K on NM_031289.5) | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.222); catalogued as COSV60971462; called by muse, mutect2, varscan2
- HCK | c.685G>A p.G229R | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV52940556; called by muse, mutect2
- HDGFL1 | c.655C>T p.P219S | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.076); catalogued as rs774702495; called by mutect2, varscan2
- HDHD2 | c.367C>T p.H123Y | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV56075927; called by muse, mutect2, varscan2
- HHIPL1 | c.939C>G p.H313Q | Missense Mutation (SNP) | VAF 57/266 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58090510; called by muse, mutect2, varscan2
- HIVEP1 | c.2760T>G p.D920E | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.045); catalogued as COSV65101417; called by muse, mutect2, varscan2
- HLX | c.1435G>A p.E479K | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.115); catalogued as COSV65044849; called by muse, mutect2, varscan2
- HPX | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56419341; called by muse, mutect2, varscan2
- HRNR | c.920C>T p.P307L | Missense Mutation (SNP) | VAF 77/270 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.042); catalogued as COSV64257945; called by muse, mutect2, varscan2
- HUWE1 | c.4162C>T p.P1388S | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.012); catalogued as COSV53345468; called by muse, mutect2, varscan2
- IFI44L | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as rs777051846, COSV60727628; called by muse, mutect2
- IFNA16 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as COSV66510056; called by muse, mutect2, varscan2
- IGHV5-51 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs371971064; called by muse, mutect2, varscan2
- ILDR2 | c.889G>A p.G297S | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54830936; called by muse, mutect2, varscan2
- IPO9 | c.1394T>G p.V465G | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV64233705; called by muse, mutect2, varscan2
- ITIH1 | c.1283T>G p.F428C | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV56254973; called by muse, mutect2
- ITSN1 | c.157T>A p.L53I | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV66083038; called by muse, mutect2, varscan2
- JAKMIP1 | c.1384G>A p.D462N | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1041829125, COSV51530477; called by muse, mutect2, varscan2
- KBTBD6 | c.123G>T p.K41N | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.157); catalogued as COSV65271302; called by muse, mutect2, varscan2
- KCNH4 | c.38C>T p.T13I | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV99236628; called by muse, mutect2, varscan2
- KCNIP4 | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as COSV62850004; called by muse, mutect2, varscan2
- KCNK13 | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as rs749400256, COSV56413137; called by muse, mutect2, varscan2
- KDM7A | c.606C>A p.D202E | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV50091485; called by muse, mutect2, varscan2
- KIF21A | c.4561-2A>C p.X1521_splice (on ENST00000361418 / NM_001378440.1; = p.X1508_splice on NM_017641.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 6/28 reads (21%) | catalogued as COSV62771489; called by muse, mutect2
- KLRC2 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 33/192 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.321); catalogued as rs777296375, COSV67899899; called by muse, mutect2, varscan2
- KPNA6 | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV101012458, COSV65360128; called by muse, mutect2, varscan2
- KRT12 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760840954, COSV52430704; called by muse, mutect2, varscan2
- KRTAP12-1 | c.250C>T p.L84F | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as COSV59962192; called by muse, mutect2, varscan2
- L3MBTL3 | c.1582C>T p.H528Y | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62386247; called by muse, mutect2, varscan2
- LECT2 | c.335G>A p.G112D | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV50847110; called by muse, mutect2
- LGSN | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); catalogued as rs755470418, COSV65726182; called by muse, mutect2, varscan2
- LIMK2 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.363); catalogued as rs765703194, COSV59182110; called by muse, mutect2, varscan2
- LRCH4 | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.74); catalogued as COSV53825993; called by muse, mutect2, varscan2
- LRFN4 | c.1312C>T p.Q438* | Nonsense Mutation (SNP) | VAF 22/107 reads (21%) | catalogued as COSV58921587; called by muse, mutect2, varscan2
- LSG1 | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs267599749, COSV54570177; called by muse, mutect2, varscan2
- LYPD4 | c.221G>A p.R74K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs782571006, COSV100419282; called by muse, mutect2, varscan2
- MAGEC1 | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.641); catalogued as COSV53571941; called by muse, mutect2, varscan2
- MAGEC1 | c.3145G>A p.V1049M | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV53572756; called by muse, mutect2, varscan2
- MAP1A | c.4697A>G p.E1566G | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.223); catalogued as COSV55808780; called by muse, mutect2, varscan2
- MAP7 | c.821T>G p.L274R | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.58); catalogued as COSV63419676; called by muse, mutect2, varscan2
- MATN1 | c.1180G>A p.D394N | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV65650073; called by muse, mutect2, varscan2
- MICALL2 | c.1316C>T p.P439L | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as rs765915317, COSV99875469; called by mutect2, varscan2
- MICALL2 | c.1315C>T p.P439S | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs754322836, COSV99875472; called by mutect2, varscan2
- MITD1 | c.390+1G>T p.X130_splice | Splice Site (SNP) | VAF 8/37 reads (22%) | catalogued as COSV99175536; called by muse, varscan2
- MORF4L1 | c.660C>T p.L220= (on ENST00000331268 / NM_206839.2; = p.L181= on NM_006791.4) | Splice Region (SNP) | VAF 11/81 reads (14%) | catalogued as COSV58704496; called by muse, mutect2, varscan2
- MSR1 | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as rs774345152, COSV50510265; called by muse, mutect2, varscan2
- MSR1 | c.301G>A p.G101R | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.656); catalogued as COSV50506846; called by muse, mutect2, varscan2
- MUC13 | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 30/185 reads (16%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.003); catalogued as rs757514971; called by muse, mutect2, varscan2
- MUC16 | c.22757C>T p.S7586F | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.068); catalogued as COSV67465775; called by muse, mutect2, varscan2
- MUC16 | c.9908G>A p.G3303E | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.033); catalogued as COSV67465793; called by muse, mutect2, varscan2
- MUC16 | c.7571C>T p.P2524L | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV67444100, COSV67465800; called by muse, mutect2, varscan2
- MUC17 | c.2950C>T p.P984S | Missense Mutation (SNP) | VAF 85/410 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs778827594, COSV60288470; called by muse, mutect2, varscan2
- MUC17 | c.12904C>T p.Q4302* | Nonsense Mutation (SNP) | VAF 10/54 reads (19%) | catalogued as COSV100072253, COSV60288478; called by muse, mutect2, varscan2
- MYC | c.1105G>A p.E369K (on ENST00000377970; = p.E384K on NM_002467.6) | Missense Mutation (SNP) | VAF 141/276 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV52372750; called by muse, mutect2, varscan2
- MYH2 | c.3395G>A p.R1132Q | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.905); catalogued as rs778993350, COSV55438236; called by muse, mutect2, varscan2
- MYOM1 | c.239C>T p.S80F | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV55291799; called by muse, mutect2, varscan2
- NCR2 | c.733C>T p.P245S | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.113); catalogued as COSV100897187; called by muse, mutect2, varscan2
- NCR2 | c.734C>T p.P245L | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV66100912; called by muse, mutect2, varscan2
- NID1 | c.316C>T p.P106S | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV51620240; called by muse, mutect2, varscan2
- NLRP5 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs373401163; called by muse, mutect2, varscan2
- NOX5 | c.2140C>T p.Q714* | Nonsense Mutation (SNP) | VAF 11/60 reads (18%) | catalogued as COSV52988825; called by muse, mutect2, varscan2
- NPAP1 | c.1685C>T p.S562F | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.043); catalogued as COSV61507005; called by muse, mutect2, varscan2
- NVL | c.1504G>T p.E502* | Nonsense Mutation (SNP) | VAF 20/79 reads (25%) | catalogued as COSV55872544; called by muse, mutect2, varscan2
- OGDHL | c.2614C>T p.P872S | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.106); catalogued as COSV65102421; called by muse, mutect2, varscan2
- OR13C8 | c.8G>A p.R3K | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58612292; called by muse, mutect2
- OR14I1 | c.175T>G p.F59V | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV61199611; called by muse, mutect2, varscan2
- OR1D5 | c.337C>T p.L113F | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as COSV101643402; called by muse, mutect2, varscan2
- OR2G6 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781430293, COSV58574400; called by muse, mutect2, varscan2
- OR2J2 | c.199C>T p.L67F | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101013251; called by muse, mutect2
- OR4K13 | c.70C>T p.Q24* | Nonsense Mutation (SNP) | VAF 5/26 reads (19%) | catalogued as COSV59859614; called by muse, mutect2
- OR4S1 | c.863G>A p.R288K | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100180133, COSV60679517; called by muse, mutect2, varscan2
- OR5AN1 | c.484G>A p.G162S | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.167); catalogued as rs772251827, COSV58322087, COSV58322165; called by muse, mutect2, varscan2
- OR5B3 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.009); catalogued as COSV58677181; called by muse, mutect2, varscan2
- OR5M1 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73202129; called by muse, mutect2, varscan2
- OR6K3 | c.248C>T p.S83F (on ENST00000368146; = p.S67F on NM_001005327.2) | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63745649; called by muse, mutect2, varscan2
- PAGE5 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV56943602; called by mutect2, varscan2
- PAPPA | c.4417G>A p.E1473K | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.084); catalogued as COSV60277762; called by muse, mutect2, varscan2
- PCDH1 | c.3509G>A p.G1170D | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as rs777658475, COSV54613979; called by muse, mutect2
- PCDH18 | c.2725G>A p.G909R | Missense Mutation (SNP) | VAF 42/174 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.523); catalogued as COSV61268377; called by muse, mutect2, varscan2
- PCDHAC2 | c.2305C>T p.P769S | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.815); catalogued as COSV53849239; called by muse, mutect2, varscan2
- PCDHB1 | c.1553G>A p.R518K | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.191); catalogued as COSV60630902; called by muse, mutect2, varscan2
- PCDHGA1 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs140226913, COSV65296451; called by muse, mutect2, varscan2
- PCNX2 | c.3950C>T p.S1317F | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV50789839, COSV50801139; called by muse, mutect2, varscan2
- PCNX3 | c.4724C>T p.S1575F | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63136783; called by muse, mutect2, varscan2
- PCSK9 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 97/467 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776150122, COSV56162186; called by muse, mutect2, varscan2
- PHF20L1 | c.814C>T p.Q272* | Nonsense Mutation (SNP) | VAF 12/65 reads (18%) | catalogued as COSV55192526; called by muse, mutect2
- PIBF1 | c.1627C>G p.Q543E | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV58323059; called by muse, mutect2, varscan2
- PKD1L1 | c.8057T>A p.F2686Y | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.184); catalogued as COSV51842482; called by muse, mutect2, varscan2
- PLD1 | c.3089C>A p.P1030H | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV100643730; called by muse, mutect2, varscan2
- PLEKHM3 | c.1990A>G p.I664V | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as COSV66816617; called by muse, mutect2, varscan2
- PLG | c.2227G>A p.E743K | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757693607, COSV57514182; called by muse, mutect2, varscan2
- PLPPR1 | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 42/226 reads (19%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV66453223; called by muse, mutect2, varscan2
- PMM1 | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.775); catalogued as COSV99347990; called by muse, mutect2, varscan2
- PNISR | c.1741A>T p.K581* | Nonsense Mutation (SNP) | VAF 24/124 reads (19%) | catalogued as COSV65079487; called by muse, mutect2, varscan2
- PNPLA5 | c.518A>G p.N173S | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.185); catalogued as COSV53374805; called by muse, mutect2, varscan2
- PODN | c.1295C>T p.T432I (on ENST00000395871; = p.T384I on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.112); catalogued as COSV57013626; called by muse, mutect2, varscan2
- POLR3B | c.2447C>T p.S816F | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as rs914501175, COSV57279140; called by muse, mutect2, varscan2
- PPARA | c.227C>T p.S76L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.441); catalogued as rs766483864, COSV53077250; called by mutect2, varscan2
- PPP2R5E | c.1318G>C p.E440Q | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.982); catalogued as rs146316789; called by muse, mutect2, varscan2
- PRRC2A | c.649G>T p.E217* | Nonsense Mutation (SNP) | VAF 17/113 reads (15%) | catalogued as COSV63224252, COSV63224550; called by muse, mutect2, varscan2
- PSD4 | c.368G>A p.R123K | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV55526753; called by muse, varscan2
- PTGES3L-AARSD1 | c.1432G>A p.E478K (on ENST00000421990 / NM_001136042.2; = p.E460K on NM_025267.3) | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.939); catalogued as COSV64182993; called by muse, mutect2, varscan2
- PTGS1 | c.1011G>A p.G337= | Splice Region (SNP) | VAF 27/126 reads (21%) | catalogued as COSV56291795; called by muse, mutect2, varscan2
- RBMXL1 | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); catalogued as COSV53101168, COSV99555467; called by muse, varscan2
- RCSD1 | c.1084C>T p.P362S | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV63258850; called by muse, mutect2
- RELA | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.997); catalogued as COSV58014771; called by muse, mutect2, varscan2
- RERE | c.2873C>T p.S958F | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.606); catalogued as COSV61942086; called by muse, mutect2, varscan2
- RGL1 | c.52C>T p.L18F | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.077); catalogued as COSV58985487; called by muse, mutect2, varscan2
- RHOXF2 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.034); catalogued as rs781986581, COSV65047831; called by muse, mutect2, varscan2
- RNF213 | c.716A>T p.Q239L | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.203); catalogued as COSV60623824; called by muse, mutect2, varscan2
- RTN2 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.601); catalogued as COSV55594081; called by muse, mutect2, varscan2
- RUSC2 | c.3236-1G>A p.X1079_splice | Splice Site (SNP) | VAF 35/214 reads (16%) | catalogued as COSV63428569; called by muse, mutect2, varscan2
- RUSC2 | c.4531C>T p.P1511S | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.003); catalogued as rs369422512, COSV63428574; called by muse, mutect2, varscan2
- SAMD3 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV63716089; called by muse, mutect2
- SCAF4 | c.1999C>T p.P667S | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.979); catalogued as COSV54587157; called by muse, mutect2, varscan2
- SCN10A | c.3902A>C p.N1301T | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as COSV71861337; called by muse, mutect2, varscan2
- SFTPA2 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 49/305 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs767317715, COSV64882540; called by muse, mutect2, varscan2
- SIGLEC9 | c.1331G>C p.W444S | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as COSV99142369; called by muse, mutect2, varscan2
- SLC1A7 | c.1594C>T p.P532S | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.057); catalogued as COSV57013635; called by muse, mutect2, varscan2
- SLC22A8 | c.866G>A p.G289E | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1001784854, COSV60324957; called by muse, mutect2, varscan2
- SLC26A3 | c.1022G>A p.G341E | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.868); catalogued as rs923181529, COSV60640273; called by muse, mutect2, varscan2
- SLC9A2 | c.789G>A p.M263I | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as COSV52131978; called by muse, mutect2, varscan2
- SPOCD1 | c.2071G>A p.D691N | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.188); catalogued as rs757160383, COSV57096392; called by muse, mutect2, varscan2
- SPP1 | c.616C>T p.P206S (on ENST00000395080 / NM_001040058.2; = p.P192S on NM_000582.2) | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.196); catalogued as rs868743585, COSV52951844; called by muse, mutect2, varscan2
- SPTBN5 | c.4494C>G p.H1498Q | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.212); catalogued as COSV58020554; called by muse, mutect2, varscan2
- SSTR1 | c.1064C>T p.A355V | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.13); catalogued as COSV57456039; called by muse, mutect2, varscan2
- ST13 | c.959C>T p.P320L | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53421842; called by muse, mutect2, varscan2
- STARD6 | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765279796, COSV57142200; called by mutect2, varscan2
- SUCO | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV55265341; called by muse, mutect2, varscan2
- SULT1C3 | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as COSV61252436; called by muse, mutect2, varscan2
- SUPT5H | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 38/166 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.096); catalogued as COSV63239654; called by muse, mutect2, varscan2
- TACR2 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.91); PolyPhen benign (0.028); catalogued as rs753219943, COSV53858192, COSV53859274; called by muse, mutect2, varscan2
- TBX21 | c.1345C>T p.R449C | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs773622233, COSV51596207; called by muse, mutect2, varscan2
- TENM1 | c.3850G>A p.D1284N | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.4); catalogued as COSV64442544, COSV64442889; called by muse, mutect2, varscan2
- TG | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143578780, COSV55069694; called by muse, mutect2, varscan2
- TMEM132B | c.314C>T p.S105F | Missense Mutation (SNP) | VAF 37/145 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.41); catalogued as COSV54753802; called by muse, mutect2, varscan2
- TMEM67 | c.2041C>T p.Q681* | Nonsense Mutation (SNP) | VAF 12/100 reads (12%) | catalogued as COSV60039345; called by muse, mutect2, varscan2
- TMF1 | c.1903C>T p.Q635* | Nonsense Mutation (SNP) | VAF 12/63 reads (19%) | catalogued as COSV68374303; called by muse, mutect2, varscan2
- TMPO | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.153); catalogued as rs1490180210, COSV58460771; called by muse, mutect2, varscan2
- TMPRSS15 | c.1354T>G p.F452V | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV53039872; called by muse, mutect2, varscan2
- TNS4 | c.1291C>T p.P431S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as COSV54185007; called by muse, mutect2, varscan2
- TRIM14 | c.622G>C p.V208L | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV58354232; called by muse, mutect2, varscan2
- TRIT1 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.101); catalogued as rs1283729380, COSV57548279; called by muse, mutect2, varscan2
- TRPM8 | c.3181G>A p.E1061K | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV61222004; called by muse, mutect2, varscan2
- TTC29 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.94); PolyPhen benign (0.007); catalogued as COSV57275392; called by muse, mutect2, varscan2
- TTLL13P | c.431T>A p.F144Y | Missense Mutation (SNP) | VAF 41/195 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV60037479; called by muse, mutect2, varscan2
- TTLL2 | c.1568C>T p.P523L | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV53443886; called by muse, mutect2, varscan2
- TTN | c.101170G>A p.G33724S (on ENST00000591111; = p.G26300S on NM_003319.4) | Missense Mutation (SNP) | VAF 15/76 reads (20%) | PolyPhen probably damaging (0.979); catalogued as COSV60060867; called by muse, mutect2, varscan2
- TTN | c.48195G>A p.W16065* (on ENST00000591111; = p.W8641* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 38/197 reads (19%) | catalogued as COSV60060921; called by muse, mutect2, varscan2
- TTN | c.25937G>A p.G8646E (on ENST00000591111; = p.G7719E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/19 reads (21%) | PolyPhen benign (0.026); catalogued as COSV60060967; called by muse, mutect2
- UGT3A1 | c.59C>T p.S20L | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.716); catalogued as rs923676353, COSV57098116; called by muse, mutect2, varscan2
- USP54 | c.2954C>T p.S985F | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV60442550; called by muse, mutect2, varscan2
- VPS13A | c.4020G>T p.W1340C | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV62429867; called by muse, mutect2, varscan2
- VPS13D | c.9949A>G p.S3317G | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV99165316; called by muse, mutect2, varscan2
- VPS13D | c.9950G>A p.S3317N | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as rs1276510995, COSV99165317; called by muse, mutect2, varscan2
- VPS13D | c.11426C>T p.P3809L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV50638721; called by muse, mutect2, varscan2
- XDH | c.3646C>T p.P1216S | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as rs767242541, COSV65148668; called by muse, mutect2, varscan2
- XIRP2 | c.2807C>T p.S936L (on ENST00000628543; = p.S1111L on NM_152381.6) | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.413); catalogued as rs771644507, COSV54695141; called by muse, mutect2
- YY1AP1 | c.1337C>T p.P446L (on ENST00000295566 / NM_139118.2; = p.P389L on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.967); catalogued as COSV55121245; called by muse, mutect2, varscan2
- ZBBX | c.1612G>A p.E538K | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.202); catalogued as COSV56788279, COSV56789317; called by muse, mutect2
- ZBED2 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV51916288; called by muse, mutect2, varscan2
- ZBTB7B | c.959C>A p.S320Y (on ENST00000292176; = p.S354Y on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0.304); catalogued as COSV52692642; called by muse, mutect2, varscan2
- ZFPL1 | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 48/249 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51869534; called by muse, mutect2, varscan2
- ZHX2 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 28/259 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs746611861, COSV58710251, COSV58715589; called by muse, mutect2, varscan2
- ZNF132 | c.1602G>A p.W534* | Nonsense Mutation (SNP) | VAF 11/49 reads (22%) | catalogued as COSV54234972; called by muse, mutect2, varscan2
- ZNF317 | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56109612; called by muse, mutect2, varscan2
- ZNF599 | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV61396193; called by muse, mutect2, varscan2
- ZNF705A | c.743G>A p.R248K | Missense Mutation (SNP) | VAF 40/221 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.076); catalogued as COSV100828307, COSV63733160; called by muse, mutect2, varscan2
- ZNF98 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.045); catalogued as COSV63336561; called by muse, varscan2
- ADGRE2 | c.677C>T p.S226F | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); called by muse, mutect2
- AREG | c.326A>G p.K109R | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); called by muse, mutect2
- BSN | c.2698A>C p.N900H | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.7); PolyPhen benign (0.006); called by muse, mutect2
- IGHG3 | c.546G>A p.M182I | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- LRRC37A3 | c.1916A>T p.K639M | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.313); called by mutect2, varscan2
- TMEM132D | c.1781_1799del p.L594Qfs*10 | Frame Shift Del (DEL) | VAF 9/73 reads (12%) | called by mutect2, pindel
- TSC1 | c.1263+1_1263+12del p.X421_splice | Splice Site (DEL) | VAF 16/128 reads (13%) | called by mutect2, pindel
- ABLIM1 | c.1650C>T p.F550= | Silent (SNP) | VAF 17/96 reads (18%) | catalogued as COSV53306152; called by muse, mutect2, varscan2
- ADAMTSL1 | c.906G>A p.R302= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as COSV52815698, COSV52819693; called by muse, mutect2, varscan2
- ADGRE1 | c.1764C>T p.A588= | Silent (SNP) | VAF 24/107 reads (22%) | catalogued as rs767928378, COSV51675490; called by muse, mutect2, varscan2
- ADGRV1 | c.18042C>T p.F6014= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV67985166; called by muse, mutect2, varscan2
- ADORA1 | c.657C>T p.S219= | Silent (SNP) | VAF 21/110 reads (19%) | catalogued as rs201016113, COSV55141536; called by muse, mutect2, varscan2
- AGTR2 | c.651C>T p.I217= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV64156108; called by muse, mutect2, varscan2
- ALOX15B | c.516C>T p.L172= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV66479443; called by muse, mutect2
- APCDD1 | c.669C>T p.L223= | Silent (SNP) | VAF 16/123 reads (13%) | catalogued as rs775364287, COSV62372493; called by muse, mutect2, varscan2
- ARFGEF1 | c.5056T>C p.L1686= | Silent (SNP) | VAF 37/78 reads (47%) | catalogued as COSV51608735; called by muse, mutect2, varscan2
- ARFGEF3 | c.5766G>A p.L1922= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs1053009403, COSV52457395, COSV99293112; called by muse, mutect2, varscan2
- ARIH2 | c.1456C>T p.L486= | Silent (SNP) | VAF 46/267 reads (17%) | catalogued as COSV62704782; called by muse, mutect2, varscan2
- ASPH | c.390C>T p.P130= | Silent (SNP) | VAF 31/68 reads (46%) | catalogued as rs575705988, COSV100727473, COSV62859199; called by muse, mutect2, varscan2
- BAZ2A | c.1863C>T p.F621= | Silent (SNP) | VAF 16/124 reads (13%) | catalogued as COSV51636736; called by muse, mutect2, varscan2
- BRCA2 | c.6201C>T p.S2067= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as CD031825, COSV66453717; called by muse, mutect2, varscan2
- C15orf39 | c.1308C>T p.A436= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as rs761152144, COSV62296686; called by muse, mutect2, varscan2
- CA9 | c.465C>T p.A155= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs1352160681, COSV65675677; called by muse, mutect2, varscan2
- CACNG2 | c.291C>T p.F97= | Silent (SNP) | VAF 29/154 reads (19%) | catalogued as COSV55635005; called by muse, mutect2, varscan2
- CBFB | c.534G>A p.K178= | Silent (SNP) | VAF 14/88 reads (16%) | catalogued as rs1354067240, COSV51998385; called by muse, mutect2, varscan2
- CCDC3 | c.802C>T p.L268= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs778978687, COSV66559783; called by muse, mutect2, varscan2
- CD244 | c.54G>A p.Q18= | Silent (SNP) | VAF 6/63 reads (10%) | catalogued as COSV100458118; called by muse, mutect2
- CD79A | c.57C>T p.F19= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as rs1357221630, COSV55738657; called by muse, mutect2, varscan2
- CDH23 | c.4134C>T p.D1378= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs1413176491, COSV56463490; called by muse, mutect2
- CELA2B | c.339C>T p.S113= | Silent (SNP) | VAF 23/104 reads (22%) | catalogued as rs747771040, COSV65545613; called by muse, mutect2, varscan2
- CER1 | c.138C>T p.N46= | Silent (SNP) | VAF 15/91 reads (16%) | catalogued as COSV66603297; called by muse, mutect2, varscan2
- CFAP43 | c.2421G>A p.R807= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV53377927; called by muse, mutect2, varscan2
- CNTNAP5 | c.1119C>T p.S373= | Silent (SNP) | VAF 20/93 reads (22%) | catalogued as COSV70485076; called by muse, mutect2, varscan2
- COASY | c.1245C>T p.L415= | Silent (SNP) | VAF 24/108 reads (22%) | catalogued as COSV55898852; called by muse, mutect2, varscan2
- COL1A1 | c.3777C>T p.C1259= | Silent (SNP) | VAF 15/89 reads (17%) | catalogued as rs1486592322, COSV56804913; called by muse, mutect2, varscan2
- CUL9 | c.969C>T p.L323= | Silent (SNP) | VAF 16/128 reads (13%) | catalogued as COSV52727636; called by muse, mutect2
- DHX33 | c.1899C>T p.A633= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs768996211, COSV56579003; called by muse, mutect2, varscan2
- DIAPH3 | c.3543C>T p.P1181= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as rs751460645, COSV100930785; called by muse, mutect2
- DNAH5 | c.6537G>A p.T2179= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs201482933, COSV54224672; called by muse, mutect2, varscan2
- DNAJC16 | c.594C>T p.V198= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as rs1173940842, COSV65448118; called by muse, mutect2, varscan2
- E2F3 | c.798C>T p.L266= | Silent (SNP) | VAF 77/436 reads (18%) | catalogued as COSV60897540; called by muse, mutect2, varscan2
- ESRRB | c.384G>A p.K128= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs760684578, COSV55061561; called by muse, mutect2, varscan2
- EVI5L | c.606C>T p.I202= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as rs763546633, COSV54484170; called by muse, mutect2, varscan2
- FAM222B | c.342G>A p.K114= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV100368120; called by muse, mutect2, varscan2
- FIG4 | c.1338C>T p.F446= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV57787589, COSV57788319; called by muse, mutect2, varscan2
- FLNC | c.1599C>T p.F533= | Silent (SNP) | VAF 26/133 reads (20%) | catalogued as rs768072902, COSV57953887; called by muse, mutect2, varscan2
- GLYCTK | c.27C>T p.P9= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV59793686; called by muse, varscan2
- GRIA1 | c.2157G>A p.E719= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV53602999; called by muse, mutect2, varscan2
- GRIN2A | c.468G>A p.T156= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as rs773513210, COSV58023406; ClinVar: likely benign; called by muse, mutect2, varscan2
- GRIN2B | c.1890C>T p.I630= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as rs748829220, COSV101663015, COSV74205931; called by muse, mutect2, varscan2
- GRM2 | c.2409C>T p.S803= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as rs971074087, COSV56584901; called by muse, mutect2, varscan2
- HCN1 | c.1095C>T p.A365= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV57510611; called by muse, mutect2, varscan2
- HIVEP2 | c.2022C>T p.F674= | Silent (SNP) | VAF 23/108 reads (21%) | catalogued as COSV50012847; called by muse, mutect2, varscan2
- HLCS | c.1638C>T p.S546= | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as rs536830110, COSV60793644; called by muse, mutect2, varscan2
- HSP90AB1 | c.546C>A p.I182= | Silent (SNP) | VAF 17/99 reads (17%) | catalogued as COSV62334522; called by muse, varscan2
- IDO1 | c.621G>A p.L207= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as rs772198770, COSV53714085; called by muse, mutect2, varscan2
- IGHG2 | c.693C>T p.P231= | Silent (SNP) | VAF 35/214 reads (16%) | called by muse, mutect2, varscan2
- IGHG4 | c.918C>T p.S306= | Silent (SNP) | VAF 27/213 reads (13%) | catalogued as rs773657647; called by muse, mutect2, varscan2
- IGHV3-73 | c.27C>T p.F9= | Silent (SNP) | VAF 52/219 reads (24%) | called by muse, mutect2, varscan2
- ITGA10 | c.1974C>T p.A658= | Silent (SNP) | VAF 43/168 reads (26%) | catalogued as COSV65197393; called by muse, mutect2, varscan2
- ITGA7 | c.1803C>T p.A601= (on ENST00000555728; = p.A557= on NM_002206.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as rs570999139, COSV57693496; ClinVar: likely benign; called by muse, mutect2, varscan2
- ITGB5 | c.888C>T p.H296= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as rs1233312912, COSV99950267; called by muse, mutect2
- JCAD | c.2388G>A p.G796= | Silent (SNP) | VAF 39/143 reads (27%) | catalogued as COSV64759616; called by muse, mutect2, varscan2
- KAT6B | c.2157C>T p.Y719= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as rs1395317029, COSV54746793; called by muse, mutect2
- KCNH4 | c.39C>T p.T13= | Silent (SNP) | VAF 30/142 reads (21%) | catalogued as COSV99236627; called by muse, mutect2, varscan2
- KCNT1 | c.3165C>T p.S1055= (on ENST00000488444; = p.S1081= on NM_020822.3) | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV53701478; called by mutect2, varscan2
- KDM7A | c.1404T>C p.L468= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as COSV50091469; called by muse, mutect2, varscan2
- KIF21B | c.276G>A p.G92= | Silent (SNP) | VAF 26/91 reads (29%) | catalogued as rs150839616, COSV59757748; called by muse, mutect2, varscan2
- LAMC3 | c.4050C>T p.P1350= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV62654162; called by muse, mutect2, varscan2
- LRP2BP | c.309G>A p.G103= | Silent (SNP) | VAF 15/78 reads (19%) | catalogued as COSV60749942; called by muse, mutect2, varscan2
- LRRC15 | c.840C>T p.S280= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as rs1363913219, COSV61650115; called by muse, mutect2, varscan2
- LRRC31 | c.402C>T p.I134= | Silent (SNP) | VAF 17/87 reads (20%) | catalogued as COSV52980968; called by muse, mutect2, varscan2
- LYPD4 | c.222G>A p.R74= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV100419295, COSV58027629; called by muse, mutect2, varscan2
- MBD5 | c.3792C>T p.F1264= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV68696409; called by muse, mutect2, varscan2
- MBOAT1 | c.783C>T p.T261= | Silent (SNP) | VAF 20/122 reads (16%) | catalogued as COSV61125031; called by muse, mutect2, varscan2
- MOXD1 | c.996G>A p.R332= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV60944416; called by muse, mutect2, varscan2
- MRPL46 | c.645C>T p.F215= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV56899943; called by muse, mutect2, varscan2
- MTDH | c.918C>T p.S306= | Silent (SNP) | VAF 12/104 reads (12%) | catalogued as rs142598802; called by muse, mutect2, varscan2
- MUC16 | c.16473G>A p.E5491= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as COSV67465785; called by muse, mutect2, varscan2
- MYO18A | c.435C>T p.S145= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV62866423; called by muse, mutect2, varscan2
- MYO18B | c.2019C>G p.V673= | Silent (SNP) | VAF 17/82 reads (21%) | catalogued as COSV59134413, COSV59139722; called by muse, mutect2, varscan2
- NEUROD4 | c.606C>T p.F202= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as COSV54471643; called by muse, mutect2, varscan2
- NIPSNAP1 | c.138C>T p.S46= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV53342594; called by muse, mutect2, varscan2
- NLRP11 | c.132G>A p.L44= | Silent (SNP) | VAF 15/82 reads (18%) | catalogued as COSV64087334; called by muse, mutect2, varscan2
- NLRP12 | c.2551C>T p.L851= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as COSV60747433; called by muse, mutect2, varscan2
- NLRP7 | c.1887C>T p.F629= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as COSV60174433; called by muse, mutect2, varscan2
- NOC2L | c.2001C>T p.L667= | Silent (SNP) | VAF 15/79 reads (19%) | catalogued as COSV58986308, COSV58987561, COSV58990300; called by muse, mutect2, varscan2
- NUP210 | c.5502C>T p.P1834= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV54406350; called by muse, mutect2, varscan2
- OAS3 | c.1278G>A p.P426= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as rs748404977, COSV57445714; called by muse, mutect2, varscan2
- OR13C5 | c.183C>T p.F61= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV66164292; called by muse, mutect2, varscan2
- OR2A7 | c.63G>A p.R21= | Silent (SNP) | VAF 27/234 reads (12%) | catalogued as COSV71827681; called by muse, mutect2, varscan2
- OR4K1 | c.738G>A p.V246= | Silent (SNP) | VAF 21/107 reads (20%) | catalogued as rs763118623, COSV53460173, COSV99578627; called by muse, mutect2, varscan2
- OR51B5 | c.21C>T p.S7= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV56176015; called by muse, mutect2
- OR5M1 | c.879G>A p.R293= | Silent (SNP) | VAF 32/143 reads (22%) | catalogued as COSV73202126; called by muse, mutect2, varscan2
- OR9A2 | c.210C>T p.I70= | Silent (SNP) | VAF 21/104 reads (20%) | catalogued as COSV63306576; called by muse, mutect2, varscan2
- PACS1 | c.756C>A p.S252= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV57697699; called by muse, mutect2, varscan2
- PCDHB13 | c.582G>A p.E194= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as rs1554287686, COSV53396516; called by muse, mutect2, varscan2
- PCDHB6 | c.1371C>T p.F457= | Silent (SNP) | VAF 49/252 reads (19%) | catalogued as rs782069574, COSV50697736; called by muse, mutect2, varscan2
- PDE6C | c.1659G>A p.R553= | Silent (SNP) | VAF 28/93 reads (30%) | catalogued as COSV65115890; called by muse, mutect2, varscan2
- PELP1 | c.1596C>T p.T532= | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as rs1478676249, COSV52587866; called by muse, mutect2, varscan2
- PHLDB1 | c.1083C>T p.I361= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV61878393; called by muse, mutect2, varscan2
- PIGR | c.1035C>T p.F345= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs373387196; called by muse, mutect2, varscan2
- PIK3C2B | c.618G>A p.R206= | Silent (SNP) | VAF 125/419 reads (30%) | catalogued as COSV65803640; called by muse, mutect2, varscan2
- PIK3R5 | c.303C>T p.L101= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as COSV52653862; called by muse, mutect2, varscan2
- PLD1 | c.3090C>T p.P1030= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV100643729; called by muse, mutect2, varscan2
- PLK1 | c.993C>T p.S331= | Silent (SNP) | VAF 20/160 reads (13%) | catalogued as COSV100266854; called by muse, mutect2, varscan2
- PLXNA3 | c.3924C>T p.F1308= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as COSV100860078, COSV63754092; called by muse, mutect2, varscan2
- PMM1 | c.462C>T p.S154= | Silent (SNP) | VAF 16/85 reads (19%) | catalogued as rs753178794, COSV53447524; called by muse, mutect2, varscan2
- POF1B | c.331C>T p.L111= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV53134105; called by muse, mutect2, varscan2
- PPM1L | c.780C>T p.I260= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV55564404; called by muse, mutect2, varscan2
- PRAMEF12 | c.261A>C p.A87= | Silent (SNP) | VAF 33/96 reads (34%) | catalogued as rs1307666709, COSV100743285, COSV63215285; called by muse, mutect2, varscan2
- PRG2 | c.9C>T p.L3= | Silent (SNP) | VAF 19/151 reads (13%) | catalogued as rs745468154, COSV61293568; called by muse, mutect2
- PRKDC | c.3660C>T p.L1220= | Silent (SNP) | VAF 6/63 reads (10%) | catalogued as rs1452146706, COSV100039496, COSV58052296; called by muse, mutect2, varscan2
- PSEN2 | c.135C>T p.A45= | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as COSV60916258; called by muse, mutect2, varscan2
- PTGS1 | c.1638G>A p.P546= | Silent (SNP) | VAF 23/124 reads (19%) | catalogued as rs1218265301, COSV56291812; called by muse, mutect2, varscan2
- PTK2B | c.1608C>T p.A536= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV57756468; called by muse, mutect2, varscan2
- PTPN11 | c.1482C>T p.I494= | Silent (SNP) | VAF 31/153 reads (20%) | catalogued as COSV61009039; called by muse, mutect2, varscan2
- RASD2 | c.165C>T p.F55= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV53352527; called by muse, mutect2, varscan2
- RPS6KC1 | c.135C>T p.V45= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV100873731, COSV65301373; called by muse, mutect2
- RREB1 | c.4425C>T p.S1475= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs531724612, COSV58558206, COSV58560315; called by mutect2, varscan2
- RTP3 | c.420C>T p.I140= | Silent (SNP) | VAF 25/124 reads (20%) | catalogued as COSV56123893; called by muse, mutect2, varscan2
- SAMD14 | c.558G>A p.K186= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV50303656; called by muse, mutect2, varscan2
- SCN8A | c.3693C>T p.I1231= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV61981569; called by muse, mutect2, varscan2
- SEMA4D | c.1788C>T p.A596= | Silent (SNP) | VAF 62/277 reads (22%) | catalogued as rs377303343, COSV59394882; called by muse, mutect2, varscan2
- SERPINB11 | c.501G>A p.K167= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as COSV66956949; called by muse, mutect2, varscan2
- SIGLEC10 | c.1197G>A p.L399= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as rs1161820939, COSV59480986; called by muse, mutect2, varscan2
- SIPA1 | c.234C>T p.A78= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV63136785; called by muse, varscan2
- SKIV2L | c.990C>T p.V330= | Silent (SNP) | VAF 204/562 reads (36%) | catalogued as rs778024754, COSV64810246; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLAMF7 | c.693C>T p.L231= | Silent (SNP) | VAF 86/255 reads (34%) | catalogued as COSV63563232; called by muse, mutect2, varscan2
- SLC22A18 | c.1149C>T p.V383= | Silent (SNP) | VAF 115/645 reads (18%) | catalogued as rs780614158, COSV56539819; called by muse, mutect2, varscan2
- SLC6A13 | c.141G>A p.G47= | Silent (SNP) | VAF 34/216 reads (16%) | catalogued as COSV58257182; called by muse, mutect2, varscan2
- SLC9A2 | c.1065C>T p.S355= | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as COSV52131986; called by muse, mutect2, varscan2
- SPACA1 | c.706T>C p.L236= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as COSV52759845; called by muse, mutect2, varscan2
- SPRED2 | c.957G>A p.E319= | Silent (SNP) | VAF 31/138 reads (22%) | catalogued as COSV62692901; called by muse, mutect2, varscan2
- SREBF1 | c.2277C>T p.A759= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV55416650; called by muse, mutect2, varscan2
- STOX1 | c.1455C>T p.S485= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV53814933; called by muse, mutect2, varscan2
- SUN5 | c.888C>T p.F296= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as rs554316199, COSV62180640; called by muse, mutect2, varscan2
- SYNPO2 | c.3042C>T p.A1014= | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as COSV61110846; called by muse, mutect2, varscan2
- SZT2 | c.969C>T p.S323= | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as COSV100986825; called by muse, mutect2, varscan2
- TAS2R3 | c.285G>A p.L95= | Silent (SNP) | VAF 46/194 reads (24%) | catalogued as rs1304740436, COSV56092020; called by muse, mutect2, varscan2
- THBD | c.1311C>T p.F437= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV65702371, COSV65703224; called by muse, mutect2, varscan2
- TMEM202 | c.216C>T p.I72= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as rs755983451, COSV58981720; called by muse, mutect2, varscan2
- TNN | c.3255C>T p.T1085= | Silent (SNP) | VAF 35/125 reads (28%) | catalogued as COSV53421446; called by muse, mutect2, varscan2
- TRPM8 | c.513C>T p.I171= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs151205278, COSV61221999; called by muse, mutect2, varscan2
- TTLL9 | c.1266A>G p.K422= | Silent (SNP) | VAF 41/179 reads (23%) | catalogued as COSV52431267; called by muse, mutect2, varscan2
- WIPF2 | c.1026C>T p.P342= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV60273712; called by muse, mutect2, varscan2
- XKR3 | c.252C>T p.I84= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV58886152; called by muse, mutect2
- ZNF217 | c.1266T>C p.P422= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV56597081; called by muse, varscan2
- ZNF804A | c.2136G>A p.G712= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV56448722; called by muse, mutect2, varscan2
- ZZEF1 | c.8454C>T p.V2818= | Silent (SNP) | VAF 37/184 reads (20%) | catalogued as rs773786679, COSV67557458; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65498134 C>T | 5'Flank (SNP) | VAF 11/46 reads (24%) | called by muse, mutect2, varscan2
- CCNQP1 | n.640C>T | RNA (SNP) | VAF 33/145 reads (23%) | catalogued as rs1312978429; called by muse, mutect2, varscan2
- GBA3 | c.59-8287G>A | Intron (SNP) | VAF 29/87 reads (33%) | called by muse, mutect2, varscan2
- HERC2P3 | n.829G>A | RNA (SNP) | VAF 25/338 reads (7%) | catalogued as rs1394482372; called by muse, mutect2
- NBPF25P | n.1919G>A | RNA (SNP) | VAF 39/172 reads (23%) | called by muse, mutect2, varscan2
- NBPF7 | n.310G>A | RNA (SNP) | VAF 66/352 reads (19%) | catalogued as rs764521576; called by muse, mutect2, varscan2
- NRG1 | c.502+30865C>T | Intron (SNP) | VAF 12/60 reads (20%) | catalogued as COSV99827226; called by muse, mutect2, varscan2
- OR2U1P | n.669C>T | RNA (SNP) | VAF 14/52 reads (27%) | called by muse, mutect2, varscan2
- RPS6KA1 | c.*208G>A | 3'UTR (SNP) | VAF 4/19 reads (21%) | catalogued as COSV100942837; called by muse, mutect2
